Somatic mutation profile of tumor specimen 0DK1WC from CCDI case PBBXCB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.2 years (4,078 days).
Specimen 0DK1WC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 850da859-d743-4bc7-9501-f2c015b6d9d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK1WH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4eef832-a1e0-48d4-96ba-cae555551a9e

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD34B | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 200/514 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775271852, COSV58613748; called by muse, mutect2, varscan2
- CLYBL | c.493A>G p.N165D | Missense Mutation (SNP) | VAF 239/575 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HOATZ | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 121/314 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- POU2F1 | c.223A>C p.N75H (on ENST00000541643 / NM_001365848.1; = p.N98H on NM_002697.4) | Missense Mutation (SNP) | VAF 144/325 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- B3GALT6 | c.732T>G p.S244= | Silent (SNP) | VAF 284/695 reads (41%) | called by muse, mutect2, varscan2
- AMPH | c.*1G>A | 3'UTR (SNP) | VAF 12/346 reads (3%) | catalogued as COSV100343711; called by muse, mutect2
